Somatic mutation profile of tumor specimen 0DKWNC from CCDI case PBBXRR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 17.9 years (6,541 days).
Specimen 0DKWNC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d61e209-970b-4250-837f-d58806dab395.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKWNO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0f4ccdf-b2ec-4fdd-ad61-1878328355d5

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM83B | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 220/869 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373419492; called by muse, mutect2, varscan2
- GUCY1A2 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 436/1427 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1390362284, COSV56476921, COSV56477435; called by muse, mutect2, varscan2
- HMGCLL1 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 202/914 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs748496553; called by muse, mutect2, varscan2
- CLMN | c.1164G>T p.L388= | Silent (SNP) | VAF 110/415 reads (27%) | called by muse, mutect2, varscan2
- LIPF | c.900T>A p.S300= | Silent (SNP) | VAF 35/752 reads (5%) | called by muse, mutect2
